CCDI case PBCCXE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d2636f79-f5ee-4791-bcf0-c85e3386a90c

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Mesenchymal chondrosarcoma: ICD-O-3 morphology code: 9240/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 14.8 years (5,391 days).

Biospecimens (3 samples)
- Sample 0DP46V: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP47J: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DP48B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
